Somatic mutation profile of tumor specimen ALCH-AEFK-TTP1-A (aliquot ALCH-AEFK-TTP1-A-1-0-D-A618-36) from ALCHEMIST case ALCH-AEFK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.6 years (22,882 days).
Specimen ALCH-AEFK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e5e1665-67ea-4d72-926d-e63e46711aa1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEFK-NB1-A (Blood Derived Normal), aliquot ALCH-AEFK-NB1-A-1-0-D-A618-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ba68602-6309-4507-b13c-336f68ec66f4

The open-access MAF lists 592 somatic variants for this specimen: 415 protein-altering or splice-affecting, 116 silent, 61 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 367, Silent 116, Intron 30, Nonsense Mutation 26, Splice Site 9, 5'UTR 8, RNA 8, 5'Flank 6, 3'UTR 6, Frame Shift Del 5, Splice Region 4, Frame Shift Ins 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DMD | c.10108C>T p.R3370* | Nonsense Mutation (SNP) | VAF 29/261 reads (11%) | catalogued as rs104894787, CM084898, CS921169, COSV58909013; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.968dup p.N323Kfs*2 | Frame Shift Ins (INS) | VAF 28/250 reads (11%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel
- TP53 | c.830G>T p.C277F | Missense Mutation (SNP) | VAF 111/704 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs763098116, CM078491, COSV52693726, COSV52826087, COSV53107923; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB11 | c.1613A>G p.Y538C | Missense Mutation (SNP) | VAF 35/281 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750975007, COSV55602321; called by muse, mutect2
- ABCC8 | c.4721C>T p.A1574V | Missense Mutation (SNP) | VAF 53/731 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as rs532325929; called by muse, mutect2
- ABCD1 | c.776G>T p.R259L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54387676; called by mutect2, varscan2
- AC131160.1 | c.11G>C p.R4P | Missense Mutation (SNP) | VAF 71/550 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.822); catalogued as COSV100226150, COSV57701900; called by muse, varscan2
- ACSS3 | c.674G>T p.G225V | Missense Mutation (SNP) | VAF 60/354 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54089963; called by muse, varscan2
- ADAMTS12 | c.3734C>G p.A1245G | Missense Mutation (SNP) | VAF 62/816 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV61269771; called by muse, mutect2
- ADAMTS8 | c.2463G>C p.E821D | Missense Mutation (SNP) | VAF 48/623 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs376504625; called by muse, mutect2
- AFF2 | c.1126C>A p.H376N | Missense Mutation (SNP) | VAF 60/566 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.858); catalogued as COSV53983774; called by muse, mutect2, varscan2
- ALPI | c.592C>A p.R198S | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.239); catalogued as COSV55014363; called by muse, mutect2, varscan2
- AMY2A | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 25/456 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70214415; called by muse, mutect2
- ANKRD30A | c.2815G>T p.V939L (on ENST00000611781; = p.V883L on NM_052997.2) | Missense Mutation (SNP) | VAF 46/294 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64612810, COSV64619683; called by muse, varscan2
- APOL3 | c.583G>T p.G195C (on ENST00000349314 / NM_145640.2; = p.G124C on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/273 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1308058231; called by muse, mutect2, varscan2
- ASTN1 | c.2770C>A p.H924N | Missense Mutation (SNP) | VAF 66/456 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs759502995, COSV62495918; called by mutect2, varscan2
- ATP6V0D2 | c.232C>A p.L78I | Missense Mutation (SNP) | VAF 26/322 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as COSV53412987; called by muse, mutect2
- CACNA1S | c.1582C>A p.R528S | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM051018, CM1411741; called by muse, mutect2, varscan2
- CATSPERG | c.3116G>T p.G1039V | Missense Mutation (SNP) | VAF 53/361 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99286314, COSV99287066; called by muse, mutect2, varscan2
- CCDC168 | c.12656G>A p.R4219K | Missense Mutation (SNP) | VAF 24/520 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV59424558; called by muse, mutect2
- CCDC89 | c.938G>T p.R313L | Missense Mutation (SNP) | VAF 27/458 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV100320928, COSV57034716; called by muse, mutect2
- CDH12 | c.152G>T p.R51L | Missense Mutation (SNP) | VAF 36/668 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV101200838, COSV66444733; called by muse, mutect2
- CECR2 | c.1299-2A>T p.X433_splice (on ENST00000342247 / NM_001290047.2; = p.X250_splice on NM_001290046.1) | Splice Site (SNP) | VAF 50/392 reads (13%) | catalogued as COSV52838073; called by muse, mutect2, varscan2
- CFAP47 | c.8006C>T p.T2669M | Missense Mutation (SNP) | VAF 12/274 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1431557641, COSV66216748; called by muse, mutect2
- CFAP57 | c.2827C>T p.R943* | Nonsense Mutation (SNP) | VAF 12/138 reads (9%) | catalogued as rs745712926; called by muse, mutect2
- CFHR4 | c.1102G>A p.A368T (on ENST00000367416 / NM_001201551.2; = p.A122T on NM_006684.5) | Missense Mutation (SNP) | VAF 27/270 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.056); catalogued as COSV52236825; called by muse, mutect2, varscan2
- CHADL | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.06); catalogued as rs1413620431; called by muse, mutect2
- CLEC3A | c.84G>T p.Q28H (on ENST00000651443; = p.Q19H on NM_005752.6) | Missense Mutation (SNP) | VAF 64/628 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV55223237; called by muse, mutect2
- COL1A2 | c.2582C>T p.P861L | Missense Mutation (SNP) | VAF 115/921 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV51961103; called by muse, mutect2, varscan2
- COL6A3 | c.3008G>A p.G1003E | Missense Mutation (SNP) | VAF 82/428 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.768); catalogued as rs775536678; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPAMD8 | c.575-2A>T p.X192_splice (on ENST00000651564; = p.X145_splice on NM_015692.5) | Splice Site (SNP) | VAF 39/335 reads (12%) | catalogued as COSV99359173; called by muse, mutect2, varscan2
- CRYBG3 | c.3485C>T p.A1162V | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0.012); catalogued as rs979517310; called by muse, mutect2
- CSMD3 | c.11107G>C p.V3703L (on ENST00000297405 / NM_001363185.1; = p.V3534L on NM_052900.3) | Missense Mutation (SNP) | VAF 58/492 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.163); catalogued as COSV52177090; called by muse, mutect2, varscan2
- CST4 | c.306C>A p.D102E | Missense Mutation (SNP) | VAF 59/489 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.042); catalogued as rs1239184078; called by muse, mutect2, varscan2
- CYLD | c.1579G>T p.A527S | Missense Mutation (SNP) | VAF 58/706 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.315); catalogued as COSV61095890; called by muse, mutect2
- CYP39A1 | c.1343A>G p.Y448C | Missense Mutation (SNP) | VAF 12/334 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs887377700; called by muse, mutect2
- DACT1 | c.1445C>T p.S482L | Missense Mutation (SNP) | VAF 16/390 reads (4%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV60020857; called by muse, mutect2
- DCAF12L2 | c.74C>A p.S25* | Nonsense Mutation (SNP) | VAF 72/473 reads (15%) | catalogued as COSV63580247; called by muse, mutect2, varscan2
- DCTN5 | c.290G>T p.C97F | Missense Mutation (SNP) | VAF 51/422 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs372198832; called by muse, mutect2, varscan2
- DLL3 | c.580C>G p.R194G | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.261); catalogued as COSV52696953; called by muse, mutect2, varscan2
- DMD | c.4951G>T p.D1651Y | Missense Mutation (SNP) | VAF 90/754 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63751990; called by muse, varscan2
- DMRT3 | c.533G>T p.R178M | Missense Mutation (SNP) | VAF 67/535 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); catalogued as COSV51905457; called by muse, mutect2, varscan2
- DRD3 | c.1120G>T p.V374L | Missense Mutation (SNP) | VAF 29/213 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.108); catalogued as rs141536671, COSV55680354; called by muse, mutect2, varscan2
- DUSP11 | c.200G>T p.R67L | Missense Mutation (SNP) | VAF 59/393 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.104); catalogued as COSV55595673; called by muse, mutect2, varscan2
- EGFL6 | c.67G>T p.A23S | Missense Mutation (SNP) | VAF 40/265 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.052); catalogued as COSV63634515; called by muse, mutect2, varscan2
- EIF4G1 | c.2218C>T p.R740W (on ENST00000346169 / NM_198241.3; = p.R545W on NM_004953.5) | Missense Mutation (SNP) | VAF 77/587 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1002506834; called by muse, mutect2, varscan2
- ERICH1 | c.952G>A p.G318R | Missense Mutation (SNP) | VAF 67/518 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.116); catalogued as rs142191174, COSV50640728, COSV50640880; called by mutect2, varscan2
- FAM163A | c.398G>A p.G133E | Missense Mutation (SNP) | VAF 12/248 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.895); catalogued as COSV59202546, COSV59205576; called by muse, mutect2
- FAM47C | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 45/414 reads (11%) | SIFT tolerated (0.98); PolyPhen benign (0.08); catalogued as COSV63726751; called by muse, mutect2, varscan2
- FCAR | c.688C>A p.R230S | Missense Mutation (SNP) | VAF 14/293 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as COSV62029502; called by muse, mutect2
- FCER1A | c.655G>C p.D219H | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63667164; called by muse, mutect2, varscan2
- FILIP1L | c.1066G>C p.E356Q (on ENST00000354552 / NM_182909.3; = p.E116Q on NM_014890.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/616 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.134); catalogued as COSV58765506, COSV58765978; called by muse, mutect2
- FOLH1 | c.1906G>A p.V636I | Missense Mutation (SNP) | VAF 15/112 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs1428970654; called by muse, varscan2
- FRMD3 | c.323G>T p.R108I | Missense Mutation (SNP) | VAF 60/454 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100418603, COSV58462757; called by muse, mutect2, varscan2
- GABRE | c.716C>A p.S239Y | Missense Mutation (SNP) | VAF 54/521 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.108); catalogued as COSV64819774; called by muse, mutect2
- GABRG2 | c.1320A>T p.R440S (on ENST00000361925 / NM_001375343.1; = p.R400S on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/698 reads (15%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.991); catalogued as COSV100729771; called by muse, mutect2, varscan2
- GPRASP1 | c.2000G>T p.G667V | Missense Mutation (SNP) | VAF 50/365 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.039); catalogued as COSV64355895; called by muse, mutect2, varscan2
- HCFC1 | c.1487C>T p.T496I | Missense Mutation (SNP) | VAF 64/486 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as rs373522421, COSV60079371; called by muse, mutect2, varscan2
- HDAC8 | c.1066C>A p.R356S | Missense Mutation (SNP) | VAF 59/513 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV101005345; called by muse, mutect2, varscan2
- HGF | c.2003C>A p.P668Q | Missense Mutation (SNP) | VAF 62/615 reads (10%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); catalogued as COSV55951999; called by muse, mutect2
- HGF | c.2002C>A p.P668T | Missense Mutation (SNP) | VAF 62/618 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.161); catalogued as COSV55945239; called by muse, mutect2
- HOXA5 | c.460C>A p.P154T | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.059); catalogued as COSV56073142; called by muse, mutect2, varscan2
- JAK1 | c.2689G>A p.E897K | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT tolerated (0.8); PolyPhen benign (0.296); catalogued as COSV61089562; called by muse, mutect2
- KCNMA1 | c.2878G>A p.G960R (on ENST00000286628 / NM_001161352.2; = p.G902R on NM_002247.4) | Missense Mutation (SNP) | VAF 58/410 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs1462137833, COSV99698336, COSV99699598; called by muse, mutect2, varscan2
- KCNQ3 | c.2379G>A p.M793I | Missense Mutation (SNP) | VAF 50/436 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.023); catalogued as rs990515326; called by muse, mutect2, varscan2
- KIAA1210 | c.3193G>T p.D1065Y | Missense Mutation (SNP) | VAF 52/398 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV68175499; called by muse, mutect2, varscan2
- KIAA1217 | c.2602G>A p.A868T | Missense Mutation (SNP) | VAF 84/495 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.115); catalogued as COSV56816313; called by muse, mutect2, varscan2
- LHX5 | c.487G>T p.D163Y | Missense Mutation (SNP) | VAF 39/230 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV99028187; called by muse, mutect2, varscan2
- LIPA | c.601G>T p.G201C | Missense Mutation (SNP) | VAF 114/812 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs1403650234; called by mutect2, varscan2
- LRRC38 | c.794C>G p.S265C | Missense Mutation (SNP) | VAF 33/512 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV65791723; called by muse, mutect2
- MAG | c.319G>A p.V107I | Missense Mutation (SNP) | VAF 30/217 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs186777043; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3536G>T p.R1179L | Missense Mutation (SNP) | VAF 38/215 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.599); catalogued as COSV99167935; called by muse, mutect2, varscan2
- MED10 | c.309+1G>T p.X103_splice | Splice Site (SNP) | VAF 95/386 reads (25%) | catalogued as rs1485665418, COSV55386395; called by muse, mutect2, varscan2
- MPDZ | c.4136G>T p.G1379V | Missense Mutation (SNP) | VAF 35/409 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs766873973; called by muse, mutect2
- MUC16 | c.40526G>A p.R13509K | Missense Mutation (SNP) | VAF 22/121 reads (18%) | SIFT tolerated, low confidence (0.38); PolyPhen possibly damaging (0.841); catalogued as COSV66689828; called by muse, mutect2, varscan2
- MUC17 | c.9451G>T p.G3151C | Missense Mutation (SNP) | VAF 31/318 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV60306889; called by muse, mutect2, varscan2
- MYH6 | c.1465T>G p.F489V | Missense Mutation (SNP) | VAF 179/663 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV62455780; called by muse, mutect2, varscan2
- NAP1L2 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 19/481 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.047); catalogued as COSV65172511; called by muse, mutect2
- NCKAP5 | c.782G>T p.R261I | Missense Mutation (SNP) | VAF 69/428 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1248711412; called by muse, mutect2, varscan2
- NDST4 | c.1675C>T p.Q559* | Nonsense Mutation (SNP) | VAF 32/218 reads (15%) | catalogued as rs867993447; called by muse, mutect2, varscan2
- NEBL | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 112/841 reads (13%) | catalogued as COSV65799968; called by muse, mutect2, varscan2
- NLRC5 | c.1894G>A p.A632T | Missense Mutation (SNP) | VAF 29/435 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.254); catalogued as rs1430050300, COSV52663326; called by muse, mutect2
- NLRP3 | c.2285C>A p.T762K | Missense Mutation (SNP) | VAF 110/726 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV60231886; called by muse, varscan2
- NOA1 | c.530C>T p.T177I | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.057); catalogued as rs770738314; called by muse, mutect2, varscan2
- NPAP1 | c.31G>T p.G11W | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.75); catalogued as COSV61507825, COSV61511976; called by muse, mutect2, varscan2
- NRXN2 | c.2344C>T p.R782C | Missense Mutation (SNP) | VAF 67/401 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs763745028; called by muse, mutect2, varscan2
- NUP62CL | c.30G>T p.L10F | Missense Mutation (SNP) | VAF 35/317 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.091); catalogued as COSV65236212; called by muse, mutect2, varscan2
- OCA2 | c.1028C>A p.A343E | Missense Mutation (SNP) | VAF 46/311 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as COSV62337728; called by muse, mutect2, varscan2
- OR6P1 | c.190G>T p.G64C | Missense Mutation (SNP) | VAF 61/424 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as rs1447203152; called by muse, mutect2, varscan2
- OR8G2P | c.104A>G p.Y35C | Missense Mutation (SNP) | VAF 25/440 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.34); catalogued as rs766802656; called by muse, mutect2
- OR8K1 | c.382C>A p.R128S | Missense Mutation (SNP) | VAF 19/278 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as rs772960419, COSV54401364; called by muse, mutect2
- PAPPA2 | c.5173G>T p.V1725F | Missense Mutation (SNP) | VAF 83/618 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV62791708; called by muse, mutect2, varscan2
- PCLO | c.4285G>A p.D1429N | Missense Mutation (SNP) | VAF 45/433 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.055); catalogued as rs752862200, COSV61643890; called by muse, mutect2, varscan2
- PDS5B | c.1580C>T p.S527L | Missense Mutation (SNP) | VAF 32/436 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.311); catalogued as COSV59722678; called by muse, mutect2
- PID1 | c.379G>C p.E127Q (on ENST00000354069 / NM_001330156.1; = p.E125Q on NM_017933.5) | Missense Mutation (SNP) | VAF 31/542 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.056); catalogued as rs746380607; called by muse, mutect2
- POTEE | c.862G>A p.V288M | Missense Mutation (SNP) | VAF 51/650 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.857); catalogued as rs772145185, COSV58225905; called by muse, mutect2
- POTEF | c.2449G>C p.E817Q | Missense Mutation (SNP) | VAF 103/817 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); catalogued as COSV62540473; called by muse, mutect2, varscan2
- PRSS1 | c.714G>T p.W238C | Missense Mutation (SNP) | VAF 130/806 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61190917; called by muse, varscan2
- PTN | c.458C>A p.S153Y | Missense Mutation (SNP) | VAF 33/264 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV61963354; called by muse, mutect2, varscan2
- PTPRC | c.3157A>T p.R1053* | Nonsense Mutation (SNP) | VAF 116/898 reads (13%) | catalogued as COSV61407126; called by muse, mutect2, varscan2
- PXDNL | c.3305G>A p.R1102Q | Missense Mutation (SNP) | VAF 41/262 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1456440086; called by muse, mutect2, varscan2
- PXDNL | c.2018G>A p.R673Q | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs745683818, COSV100687452; called by muse, mutect2, varscan2
- RBM33 | c.3070G>T p.V1024L | Missense Mutation (SNP) | VAF 28/221 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1009824368, COSV62032735; called by muse, mutect2, varscan2
- RHOXF1 | c.8G>T p.R3L | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as COSV54294700; called by muse, varscan2
- RUFY4 | c.1555G>A p.E519K | Missense Mutation (SNP) | VAF 52/442 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs749470049; called by muse, mutect2, varscan2
- RYR3 | c.4886A>T p.Y1629F | Missense Mutation (SNP) | VAF 79/452 reads (17%) | SIFT tolerated (0.8); PolyPhen benign (0.007); catalogued as COSV66779934; called by muse, mutect2, varscan2
- RYR3 | c.12838C>A p.L4280I (on ENST00000389232; = p.L4281I on NM_001036.6) | Missense Mutation (SNP) | VAF 79/590 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV66790668; called by muse, mutect2, varscan2
- SEPTIN14 | c.1149G>T p.M383I | Missense Mutation (SNP) | VAF 50/782 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV66426856; called by muse, mutect2
- SHISA6 | c.1024C>A p.P342T (on ENST00000409168 / NM_001173461.1; = p.P393T on NM_207386.4) | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV69394834; called by muse, mutect2, varscan2
- SIM1 | c.903C>A p.H301Q | Missense Mutation (SNP) | VAF 38/446 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as rs914170564; called by muse, mutect2
- SLC12A3 | c.1006C>A p.P336T | Missense Mutation (SNP) | VAF 28/327 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.261); catalogued as COSV99344291; called by muse, mutect2
- SLC25A21 | c.644T>A p.L215H | Missense Mutation (SNP) | VAF 15/222 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as rs1385967684; called by muse, mutect2
- SLC29A3 | c.1012G>C p.G338R | Missense Mutation (SNP) | VAF 56/252 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as COSV64385128; called by muse, mutect2, varscan2
- SLC4A9 | c.1849C>G p.R617G (on ENST00000507527 / NM_001258428.2; = p.R593G on NM_031467.3) | Missense Mutation (SNP) | VAF 68/354 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.38); catalogued as COSV50218642; called by muse, mutect2, varscan2
- SLC5A12 | c.1766G>A p.G589E | Missense Mutation (SNP) | VAF 26/230 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV68448104; called by muse, varscan2
- SLC8A1 | c.1777G>C p.G593R | Missense Mutation (SNP) | VAF 18/145 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60481016; called by muse, mutect2, varscan2
- SLFN11 | c.356G>T p.R119L | Missense Mutation (SNP) | VAF 69/378 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV57697607, COSV57697864; called by muse, mutect2, varscan2
- SPANXN3 | c.333G>T p.E111D | Missense Mutation (SNP) | VAF 47/387 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.987); catalogued as COSV100980764; called by muse, mutect2, varscan2
- SPATA4 | c.416G>T p.G139V | Missense Mutation (SNP) | VAF 25/242 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54590054; called by muse, mutect2
- SSR2 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 49/308 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs562691742; called by muse, mutect2, varscan2
- SWAP70 | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 57/400 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1414545802; called by muse, mutect2, varscan2
- SYNDIG1 | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 69/456 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.212); catalogued as rs761095102; called by muse, mutect2, varscan2
- SYNPO2 | c.2806G>A p.A936T | Missense Mutation (SNP) | VAF 96/746 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs755395998; called by muse, mutect2, varscan2
- TERT | c.2908A>T p.M970L | Missense Mutation (SNP) | VAF 61/758 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.048); catalogued as CM1212641; called by muse, mutect2
- TK1 | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 35/228 reads (15%) | catalogued as COSV56745560; called by muse, mutect2, varscan2
- TLR8 | c.1583C>A p.A528D (on ENST00000218032 / NM_138636.5; = p.A546D on NM_016610.4) | Missense Mutation (SNP) | VAF 23/205 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.156); catalogued as COSV99486703; called by muse, mutect2, varscan2
- TMC1 | c.1270T>A p.F424I | Missense Mutation (SNP) | VAF 91/536 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52775312; called by muse, mutect2, varscan2
- TMTC2 | c.580G>T p.A194S | Missense Mutation (SNP) | VAF 39/271 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV58258767, COSV58277277; called by muse, mutect2, varscan2
- TNK2 | c.2110G>T p.A704S | Missense Mutation (SNP) | VAF 34/311 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.018); catalogued as rs762787633; called by muse, mutect2, varscan2
- TOB2 | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 21/233 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as rs143698818; called by muse, mutect2
- TOX2 | c.1201C>A p.P401T (on ENST00000358131 / NM_001098798.2; = p.P377T on NM_032883.3) | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.272); catalogued as rs778012248, COSV57885075; called by muse, mutect2, varscan2
- TTN | c.69153G>C p.Q23051H (on ENST00000591111; = p.Q15627H on NM_003319.4) | Missense Mutation (SNP) | VAF 18/345 reads (5%) | PolyPhen benign (0.26); catalogued as COSV60044334; called by muse, mutect2
- UIMC1 | c.1355C>T p.S452F | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1471727316, COSV101022229; called by muse, mutect2, varscan2
- VDR | c.956G>T p.G319V | Missense Mutation (SNP) | VAF 80/476 reads (17%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.931); catalogued as CM087887; called by muse, mutect2, varscan2
- WWC3 | c.1177G>C p.D393H | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101081536; called by muse, mutect2
- ZBTB17 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs148471565; called by muse, mutect2, varscan2
- ZC3HAV1 | c.169G>T p.E57* | Nonsense Mutation (SNP) | VAF 34/242 reads (14%) | catalogued as COSV54295707; called by muse, mutect2, varscan2
- ZDHHC14 | c.1071C>T p.C357= | Splice Region (SNP) | VAF 30/280 reads (11%) | catalogued as rs373529377; called by muse, mutect2, varscan2
- ZEB2 | c.649G>T p.D217Y | Missense Mutation (SNP) | VAF 100/736 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs755199698, COSV57956903; called by muse, varscan2
- ZKSCAN1 | c.70G>A p.V24I | Missense Mutation (SNP) | VAF 35/263 reads (13%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.939); catalogued as rs752326422; called by muse, mutect2, varscan2
- ZNF680 | c.699G>T p.M233I | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.173); catalogued as COSV59018434; called by muse, mutect2, varscan2
- ABCA8 | c.1885C>T p.L629F | Missense Mutation (SNP) | VAF 59/380 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- ABHD11 | c.150G>C p.P50= | Splice Region (SNP) | VAF 12/304 reads (4%) | called by muse, mutect2
- AC011005.1 | c.680T>A p.V227E | Missense Mutation (SNP) | VAF 64/412 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ACSS3 | c.673G>T p.G225C | Missense Mutation (SNP) | VAF 62/351 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM11 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 45/362 reads (12%) | called by muse, mutect2, varscan2
- ADAM19 | c.2756G>A p.G919E | Missense Mutation (SNP) | VAF 71/424 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS20 | c.1715G>T p.C572F | Missense Mutation (SNP) | VAF 71/433 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY8 | c.2944G>T p.G982W | Missense Mutation (SNP) | VAF 49/319 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRL3 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 60/409 reads (15%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- AGPS | c.410G>T p.G137V | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, varscan2
- AHNAK2 | c.11157G>T p.E3719D | Missense Mutation (SNP) | VAF 116/476 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- AKR1B1 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 123/855 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- AKTIP | c.160A>T p.T54S | Missense Mutation (SNP) | VAF 44/935 reads (5%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2
- ALG13 | c.3088C>T p.P1030S | Missense Mutation (SNP) | VAF 35/534 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.01); called by muse, mutect2
- ALK | c.2603T>C p.L868P | Missense Mutation (SNP) | VAF 83/563 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ANK2 | c.881C>G p.A294G | Missense Mutation (SNP) | VAF 106/943 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ANTXR2 | c.1014del p.W338Cfs*71 | Frame Shift Del (DEL) | VAF 51/401 reads (13%) | called by mutect2, pindel, varscan2
- AOC3 | c.621C>A p.N207K | Missense Mutation (SNP) | VAF 47/332 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- APBA1 | c.169C>A p.L57I | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP15 | c.288G>T p.K96N | Missense Mutation (SNP) | VAF 19/165 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ARHGAP4 | c.1982G>T p.G661V | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ARHGAP6 | c.2405C>A p.A802D (on ENST00000337414 / NM_013427.3; = p.A599D on NM_013423.3) | Missense Mutation (SNP) | VAF 20/157 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ARHGEF6 | c.1162C>A p.Q388K | Missense Mutation (SNP) | VAF 67/483 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ARHGEF7 | c.2329G>T p.A777S (on ENST00000646102 / NM_001354046.1; = p.A561S on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/282 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ARMC4 | c.2140G>T p.G714* | Nonsense Mutation (SNP) | VAF 34/309 reads (11%) | called by muse, mutect2
- ARMCX2 | c.167G>T p.G56V | Missense Mutation (SNP) | VAF 42/327 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- ASH1L | c.6559A>T p.R2187W (on ENST00000368346 / NM_001366177.2; = p.R2182W on NM_018489.3) | Missense Mutation (SNP) | VAF 31/274 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASH1L | c.1506G>T p.Q502H | Missense Mutation (SNP) | VAF 42/315 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ASIC4 | c.762G>T p.Q254H | Missense Mutation (SNP) | VAF 46/281 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- ASPM | c.607G>T p.G203C | Missense Mutation (SNP) | VAF 53/497 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- ATG4A | c.451G>T p.V151F | Missense Mutation (SNP) | VAF 49/440 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ATP11AUN | n.1019T>C | Splice Region (SNP) | VAF 18/147 reads (12%) | called by muse, mutect2, varscan2
- ATP11C | c.731C>A p.P244H | Missense Mutation (SNP) | VAF 28/238 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, varscan2
- ATP2B3 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 43/298 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ATP7A | c.568G>T p.E190* | Nonsense Mutation (SNP) | VAF 36/332 reads (11%) | called by muse, mutect2, varscan2
- ATRX | c.4627G>A p.E1543K | Missense Mutation (SNP) | VAF 61/431 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- BCL9L | c.2998del p.M1000Wfs*31 | Frame Shift Del (DEL) | VAF 28/311 reads (9%) | called by mutect2, pindel*
- BIRC6 | c.3844A>T p.S1282C | Missense Mutation (SNP) | VAF 48/326 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- BRWD3 | c.5386C>A p.H1796N | Missense Mutation (SNP) | VAF 47/313 reads (15%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- BRWD3 | c.4351C>A p.R1451S | Missense Mutation (SNP) | VAF 73/570 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- BVES | c.98C>A p.T33N | Missense Mutation (SNP) | VAF 32/344 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2
- C14orf39 | c.77C>G p.T26S | Missense Mutation (SNP) | VAF 34/160 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- C1QA | c.311G>T p.G104V | Missense Mutation (SNP) | VAF 42/482 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- C1QC | c.640G>T p.G214C | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- C5orf34 | c.1634G>C p.R545T | Missense Mutation (SNP) | VAF 118/483 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, varscan2
- C6orf141 | c.161C>G p.A54G | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- C7 | c.344A>G p.D115G | Missense Mutation (SNP) | VAF 141/588 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C9 | c.211G>T p.G71* | Nonsense Mutation (SNP) | VAF 42/739 reads (6%) | called by muse, mutect2
- CA4 | c.496C>A p.L166M | Missense Mutation (SNP) | VAF 60/360 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CACNA1H | c.5315G>T p.G1772V | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CACNA1I | c.2912G>T p.R971L | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CBLB | c.729G>T p.W243C | Missense Mutation (SNP) | VAF 53/400 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC138 | c.1657G>T p.V553F | Missense Mutation (SNP) | VAF 40/285 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- CCDC186 | c.1494A>T p.L498F | Missense Mutation (SNP) | VAF 28/239 reads (12%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC85B | c.349T>A p.W117R | Missense Mutation (SNP) | VAF 9/72 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- CCKAR | c.409C>A p.L137I | Missense Mutation (SNP) | VAF 67/437 reads (15%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.557); called by muse, mutect2, varscan2
- CCM2 | c.616G>C p.A206P | Missense Mutation (SNP) | VAF 72/516 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CD93 | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 67/487 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- CDH24 | c.2373dup p.G792Rfs*103 | Frame Shift Ins (INS) | VAF 20/97 reads (21%) | called by mutect2, pindel, varscan2
- CDH4 | c.808A>T p.M270L | Missense Mutation (SNP) | VAF 59/402 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CDH4 | c.1856A>T p.E619V | Missense Mutation (SNP) | VAF 52/449 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- CDH9 | c.251G>C p.G84A | Missense Mutation (SNP) | VAF 26/134 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2
- CDK11A | c.1931C>T p.T644I (on ENST00000378633 / NM_001313896.2; = p.T641I on NM_024011.4) | Missense Mutation (SNP) | VAF 29/190 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CHRNB2 | c.19C>G p.P7A | Missense Mutation (SNP) | VAF 40/366 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CHST1 | c.737C>T p.T246I | Missense Mutation (SNP) | VAF 11/211 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- CLCA2 | c.460G>C p.G154R | Missense Mutation (SNP) | VAF 32/160 reads (20%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- CLTC | c.3833T>A p.V1278E | Missense Mutation (SNP) | VAF 43/440 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.286); called by muse, mutect2, varscan2
- CNKSR2 | c.2333G>T p.S778I | Missense Mutation (SNP) | VAF 32/260 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, varscan2
- COL3A1 | c.511G>T p.G171C | Missense Mutation (SNP) | VAF 99/695 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL4A6 | c.4958G>T p.W1653L | Missense Mutation (SNP) | VAF 83/603 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- CPN2 | c.191T>C p.L64S | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.028); called by muse, varscan2
- CROCC | c.2347G>A p.A783T | Missense Mutation (SNP) | VAF 25/310 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.082); called by muse, mutect2
- CYLD | c.1580C>T p.A527V | Missense Mutation (SNP) | VAF 58/706 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.265); called by muse, mutect2
- CYP26C1 | c.814C>T p.H272Y | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- CYP4F12 | c.803A>T p.D268V | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- CYP4F2 | c.154C>A p.P52T | Missense Mutation (SNP) | VAF 47/226 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- CYYR1 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 49/583 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.036); called by muse, mutect2
- DACH2 | c.1481A>T p.E494V | Missense Mutation (SNP) | VAF 57/380 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- DCAF13 | c.953A>T p.E318V | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2
- DIP2A | c.1684G>T p.G562C | Missense Mutation (SNP) | VAF 53/489 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DIP2B | c.3382C>T p.P1128S | Missense Mutation (SNP) | VAF 55/445 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH14 | c.6832G>A p.E2278K (on ENST00000445597; = p.E2931K on NM_001367479.1) | Missense Mutation (SNP) | VAF 32/294 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- DNAJC10 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 41/375 reads (11%) | called by muse, mutect2, varscan2
- DOT1L | c.1226del p.R409Pfs*9 | Frame Shift Del (DEL) | VAF 54/354 reads (15%) | called by mutect2, pindel*, varscan2
- ECEL1 | c.1861T>C p.W621R | Missense Mutation (SNP) | VAF 23/176 reads (13%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EDNRB | c.797T>A p.L266Q (on ENST00000377211 / NM_001201397.1; = p.L176Q on NM_000115.5) | Missense Mutation (SNP) | VAF 39/535 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- EFCAB10 | c.145C>A p.L49M | Missense Mutation (SNP) | VAF 43/272 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- EML6 | c.3467G>A p.R1156K | Missense Mutation (SNP) | VAF 22/193 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.81); called by muse, varscan2
- ETV3L | c.104G>C p.G35A | Missense Mutation (SNP) | VAF 56/393 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FADD | c.398A>T p.Y133F | Missense Mutation (SNP) | VAF 31/387 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.035); called by muse, mutect2
- FAM155B | c.116G>T p.R39L | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- FAM160A2 | c.1858G>T p.A620S (on ENST00000449352 / NM_001098794.2; = p.A634S on NM_032127.4) | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2
- FAM214A | c.1348G>T p.E450* | Nonsense Mutation (SNP) | VAF 25/227 reads (11%) | called by muse, mutect2, varscan2
- FBN2 | c.5633G>T p.C1878F | Missense Mutation (SNP) | VAF 140/873 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FKBP2 | c.113G>T p.R38L | Missense Mutation (SNP) | VAF 4/56 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2
- FLG2 | c.4019C>G p.S1340C | Missense Mutation (SNP) | VAF 59/439 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- FMO3 | c.462C>A p.N154K | Missense Mutation (SNP) | VAF 68/575 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.022); called by muse, mutect2
- FOXD4L3 | c.865G>T p.A289S | Missense Mutation (SNP) | VAF 25/140 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.021); called by mutect2, varscan2
- FUT9 | c.566T>G p.V189G | Missense Mutation (SNP) | VAF 35/531 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- G6PC | c.659C>A p.A220D | Missense Mutation (SNP) | VAF 44/374 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- GABRB1 | c.1032A>T p.Q344H | Missense Mutation (SNP) | VAF 62/453 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.273); called by muse, mutect2, varscan2
- GABRG2 | c.32G>T p.S11I | Missense Mutation (SNP) | VAF 94/766 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- GABRG2 | c.1321G>A p.D441N (on ENST00000361925 / NM_001375343.1; = p.D401N on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/701 reads (15%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GHR | c.263G>T p.R88I | Missense Mutation (SNP) | VAF 52/918 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.82); called by muse, mutect2
- GLDC | c.623A>C p.Q208P | Missense Mutation (SNP) | VAF 50/343 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- GLI2 | c.2951G>T p.C984F (on ENST00000361492 / NM_001374353.1; = p.C1001F on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/332 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- GLIS3 | c.107T>A p.L36Q | Missense Mutation (SNP) | VAF 163/1194 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- GOLGA3 | c.2520A>T p.K840N | Missense Mutation (SNP) | VAF 49/329 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GOLGA6L2 | c.1862G>A p.G621E | Missense Mutation (SNP) | VAF 77/651 reads (12%) | SIFT tolerated, low confidence (0.07); called by muse, mutect2, varscan2
- GOLGA8K | c.1230C>A p.N410K | Missense Mutation (SNP) | VAF 81/716 reads (11%) | SIFT tolerated (0.38); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GPATCH3 | c.940G>T p.E314* | Nonsense Mutation (SNP) | VAF 57/342 reads (17%) | called by muse, mutect2, varscan2
- GPHN | c.149del p.G50Vfs*9 | Frame Shift Del (DEL) | VAF 23/312 reads (7%) | called by mutect2, pindel*
- GPRASP1 | c.1999G>T p.G667W | Missense Mutation (SNP) | VAF 51/368 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- GRM8 | c.881C>G p.A294G | Missense Mutation (SNP) | VAF 32/217 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- GTF3C1 | c.435G>T p.W145C | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- HAUS7 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 59/488 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- HCN2 | c.1135C>A p.H379N | Missense Mutation (SNP) | VAF 29/207 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- HEPH | c.1315G>A p.E439K (on ENST00000343002; = p.E172K on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/228 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0.067); called by muse, mutect2
- HHIPL2 | c.712G>T p.V238L | Missense Mutation (SNP) | VAF 62/553 reads (11%) | SIFT tolerated (0.43); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- HK3 | c.878C>G p.T293S | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- HLTF | c.1161-1G>A p.X387_splice | Splice Site (SNP) | VAF 36/218 reads (17%) | called by muse, mutect2, varscan2
- HMGXB3 | c.1852C>T p.Q618* (on ENST00000613459; = p.Q372* on NM_014983.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 31/244 reads (13%) | called by muse, mutect2, varscan2
- HOGA1 | c.567C>G p.H189Q | Missense Mutation (SNP) | VAF 66/422 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HSPA6 | c.535A>C p.T179P | Missense Mutation (SNP) | VAF 34/250 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HUWE1 | c.8416C>A p.P2806T | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGHM | c.733C>A p.L245M | Missense Mutation (SNP) | VAF 56/1095 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.826); called by muse, mutect2
- IGLV3-12 | c.23T>G p.L8R | Missense Mutation (SNP) | VAF 47/376 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- IGSF22 | c.2540C>A p.S847Y (on ENST00000319338; = p.S948Y on NM_173588.4) | Missense Mutation (SNP) | VAF 112/812 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- IL17C | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- ILDR2 | c.190G>T p.D64Y | Missense Mutation (SNP) | VAF 47/408 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITGA6 | c.2439A>C p.E813D (on ENST00000442250; = p.E774D on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 87/676 reads (13%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- JPH2 | c.766G>T p.G256C | Missense Mutation (SNP) | VAF 58/430 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- KCTD15 | c.235G>T p.D79Y | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); called by muse, varscan2
- KIF4A | c.1453G>T p.A485S | Missense Mutation (SNP) | VAF 25/232 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- KLHL34 | c.1729G>A p.G577S | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KRBOX1 | c.251G>T p.R84M | Missense Mutation (SNP) | VAF 34/408 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.907); called by muse, mutect2
- KRTAP5-3 | c.423T>G p.C141W | Missense Mutation (SNP) | VAF 118/789 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, varscan2
- L3MBTL1 | c.556G>A p.D186N (on ENST00000418998 / NM_001377303.1; = p.D96N on NM_015478.7) | Missense Mutation (SNP) | VAF 54/378 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- LAMA4 | c.1551+8G>T | Splice Region (SNP) | VAF 52/772 reads (7%) | called by muse, mutect2
- LIMS2 | c.906G>T p.K302N (on ENST00000355119 / NM_001161403.3; = p.K326N on NM_017980.4) | Missense Mutation (SNP) | VAF 30/261 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- LRCH1 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- LRRC23 | c.505A>T p.M169L | Missense Mutation (SNP) | VAF 45/264 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGED1 | c.1687C>T p.L563F | Missense Mutation (SNP) | VAF 44/337 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MAP4K2 | c.877C>T p.H293Y | Missense Mutation (SNP) | VAF 23/229 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- MAP6D1 | c.340G>T p.G114W | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2
- MATN4 | c.1055A>T p.Q352L (on ENST00000372754; = p.Q311L on NM_003833.4) | Missense Mutation (SNP) | VAF 48/476 reads (10%) | PolyPhen benign (0.066); called by muse, mutect2, varscan2
- MDGA2 | c.2753G>C p.G918A (on ENST00000399232 / NM_001113498.2; = p.G620A on NM_182830.4) | Missense Mutation (SNP) | VAF 14/227 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- MEGF8 | c.5248T>C p.W1750R (on ENST00000251268 / NM_001271938.2; = p.W1683R on NM_001410.3) | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MGA | c.3343G>T p.G1115* | Nonsense Mutation (SNP) | VAF 66/430 reads (15%) | called by muse, mutect2, varscan2
- MLLT1 | c.276G>T p.K92N | Missense Mutation (SNP) | VAF 46/266 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- MPDZ | c.4135G>C p.G1379R | Missense Mutation (SNP) | VAF 32/408 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MS4A8 | c.624G>T p.Q208H | Missense Mutation (SNP) | VAF 42/570 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.533); called by muse, mutect2
- MST1 | c.452A>G p.K151R | Missense Mutation (SNP) | VAF 41/381 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- MTUS2 | c.3787C>A p.L1263M (on ENST00000612955 / NM_001366650.1; = p.L242M on NM_015233.6) | Missense Mutation (SNP) | VAF 33/222 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NACAD | c.373A>G p.T125A | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- NBEA | c.7348G>T p.G2450* | Nonsense Mutation (SNP) | VAF 14/166 reads (8%) | called by muse, mutect2
- NBEA | c.8674T>A p.C2892S | Missense Mutation (SNP) | VAF 23/329 reads (7%) | SIFT tolerated (0.46); PolyPhen benign (0.006); called by muse, mutect2
- NDST4 | c.362C>A p.T121K | Missense Mutation (SNP) | VAF 40/283 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- NEK10 | c.2479C>T p.H827Y | Missense Mutation (SNP) | VAF 56/563 reads (10%) | SIFT tolerated (0.25); PolyPhen benign (0.058); called by muse, mutect2
- NEK5 | c.1343A>T p.E448V | Missense Mutation (SNP) | VAF 25/456 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.084); called by muse, mutect2
- NOD2 | c.2168C>A p.P723Q | Missense Mutation (SNP) | VAF 30/492 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NOMO1 | c.1123T>A p.Y375N | Missense Mutation (SNP) | VAF 44/772 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2
- NOTCH2 | c.7339G>T p.G2447C | Missense Mutation (SNP) | VAF 26/353 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); called by muse, mutect2
- NPBWR2 | c.630G>T p.K210N | Missense Mutation (SNP) | VAF 18/123 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- NR2F1 | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 57/282 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NUGGC | c.852A>C p.E284D | Missense Mutation (SNP) | VAF 74/506 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OLFM3 | c.47C>A p.A16E | Missense Mutation (SNP) | VAF 39/324 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- OLFM4 | c.118G>T p.V40F | Missense Mutation (SNP) | VAF 52/522 reads (10%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR13H1 | c.161A>T p.N54I | Missense Mutation (SNP) | VAF 66/390 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- OR4K17 | c.245T>A p.I82N | Missense Mutation (SNP) | VAF 22/448 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- OR51E2 | c.118G>T p.G40* | Nonsense Mutation (SNP) | VAF 29/617 reads (5%) | called by muse, mutect2
- OTOG | c.1018C>A p.P340T | Missense Mutation (SNP) | VAF 16/193 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.036); called by muse, mutect2
- PAK3 | c.92G>T p.S31I | Missense Mutation (SNP) | VAF 93/793 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PAPPA2 | c.1040T>A p.V347E | Missense Mutation (SNP) | VAF 91/792 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- PASK | c.3032G>T p.G1011V | Missense Mutation (SNP) | VAF 42/467 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PAX8 | c.944C>A p.S315Y | Missense Mutation (SNP) | VAF 30/183 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- PCDH10 | c.2678G>T p.R893L | Missense Mutation (SNP) | VAF 36/295 reads (12%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.573); called by muse, mutect2, varscan2
- PCDHB2 | c.1957C>T p.P653S | Missense Mutation (SNP) | VAF 88/478 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- PDE11A | c.904G>T p.A302S | Missense Mutation (SNP) | VAF 43/398 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- PDE3A | c.841G>T p.E281* | Nonsense Mutation (SNP) | VAF 17/122 reads (14%) | called by muse, mutect2, varscan2
- PDE4B | c.1172A>G p.Y391C | Missense Mutation (SNP) | VAF 30/386 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- PES1 | c.625C>T p.H209Y | Missense Mutation (SNP) | VAF 61/370 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- PIEZO2 | c.5486C>A p.P1829H | Missense Mutation (SNP) | VAF 49/319 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PIK3CG | c.224G>A p.W75* | Nonsense Mutation (SNP) | VAF 26/176 reads (15%) | called by muse, mutect2, varscan2
- PKHD1 | c.3599G>T p.S1200I | Missense Mutation (SNP) | VAF 79/1071 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- PLCD4 | c.1460C>A p.P487H | Missense Mutation (SNP) | VAF 36/265 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- PLCG2 | c.1927T>A p.S643T | Missense Mutation (SNP) | VAF 18/155 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- POLR2M | c.104dup p.L35Ffs*15 | Frame Shift Ins (INS) | VAF 17/97 reads (18%) | called by mutect2, pindel, varscan2
- POLR3B | c.1709A>G p.E570G | Missense Mutation (SNP) | VAF 70/351 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- PREX2 | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 18/379 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- PRG4 | c.2231C>A p.T744N | Missense Mutation (SNP) | VAF 111/868 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, varscan2
- PRLR | c.1834C>A p.L612M | Missense Mutation (SNP) | VAF 51/191 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- PSEN2 | c.-20-2A>T | Splice Site (SNP) | VAF 70/513 reads (14%) | called by muse, mutect2, varscan2
- PSMG1 | c.109G>T p.V37L | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.009); called by muse, varscan2
- PTK2 | c.2374A>T p.T792S | Missense Mutation (SNP) | VAF 40/267 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPRZ1 | c.3340G>A p.E1114K | Missense Mutation (SNP) | VAF 40/305 reads (13%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- RAD18 | c.518G>T p.R173L | Missense Mutation (SNP) | VAF 50/644 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2
- RAPGEF4 | c.1883A>C p.K628T | Missense Mutation (SNP) | VAF 56/458 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RARB | c.630+2T>A p.X210_splice (on ENST00000383772 / NM_001290216.2; = p.X203_splice on NM_000965.5 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 17/165 reads (10%) | called by muse, varscan2
- RBBP6 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 14/268 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- RC3H2 | c.1607G>T p.G536V | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- RCSD1 | c.398G>T p.R133M | Missense Mutation (SNP) | VAF 77/647 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- REEP4 | c.266G>T p.R89L | Missense Mutation (SNP) | VAF 48/432 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RELN | c.7198T>A p.S2400T | Missense Mutation (SNP) | VAF 47/382 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- RNF180 | c.424A>T p.R142* | Nonsense Mutation (SNP) | VAF 58/395 reads (15%) | called by muse, mutect2, varscan2
- RTN1 | c.419C>A p.P140H | Missense Mutation (SNP) | VAF 34/301 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- RTTN | c.2723G>T p.C908F | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.013); called by muse, mutect2
- RYR2 | c.7853G>T p.W2618L | Missense Mutation (SNP) | VAF 47/362 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RYR3 | c.9828-1G>T p.X3276_splice (on ENST00000389232; = p.X3277_splice on NM_001036.6) | Splice Site (SNP) | VAF 48/233 reads (21%) | called by muse, mutect2, varscan2
- SCNN1G | c.1716G>A p.W572* | Nonsense Mutation (SNP) | VAF 72/467 reads (15%) | called by muse, mutect2, varscan2
- SHISA9 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 47/474 reads (10%) | called by muse, mutect2
- SIL1 | c.590C>G p.S197C | Missense Mutation (SNP) | VAF 56/818 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2
- SLC17A1 | c.1073T>A p.L358Q | Missense Mutation (SNP) | VAF 31/239 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC22A16 | c.13C>A p.H5N | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SLC41A3 | c.1315G>T p.D439Y | Missense Mutation (SNP) | VAF 82/518 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLITRK6 | c.1655T>A p.L552H | Missense Mutation (SNP) | VAF 28/388 reads (7%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.781); called by muse, mutect2
- SMU1 | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 49/455 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SNTG2 | c.1555G>T p.A519S | Missense Mutation (SNP) | VAF 52/484 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SOX9 | c.1411C>A p.P471T | Missense Mutation (SNP) | VAF 65/495 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SP9 | c.59T>A p.L20Q | Missense Mutation (SNP) | VAF 42/336 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SPAM1 | c.1520G>T p.R507I | Missense Mutation (SNP) | VAF 41/294 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPATA33 | c.14C>A p.A5D | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.534); called by muse, mutect2, varscan2
- SPEG | c.5523-2A>T p.X1841_splice | Splice Site (SNP) | VAF 55/414 reads (13%) | called by muse, mutect2, varscan2
- STARD13 | c.556G>T p.V186F (on ENST00000336934 / NM_001243476.3; = p.V68F on NM_052851.3) | Missense Mutation (SNP) | VAF 35/428 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2
- STK32A | c.62A>T p.D21V | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- SWT1 | c.2034A>T p.L678F | Missense Mutation (SNP) | VAF 41/251 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- SYCP2 | c.3826G>A p.V1276I | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2
- SYNE1 | c.24643-1G>A p.X8215_splice (on ENST00000367255 / NM_182961.4; = p.X8144_splice on NM_033071.3) | Splice Site (SNP) | VAF 43/276 reads (16%) | called by muse, mutect2, varscan2
- TBC1D25 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 26/249 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBC1D9 | c.3626G>T p.W1209L | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- TESPA1 | c.815G>C p.R272P (on ENST00000316577 / NM_001098815.3; = p.R134P on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 98/588 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TLL1 | c.1901G>T p.W634L | Missense Mutation (SNP) | VAF 65/466 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TM4SF4 | c.166G>T p.G56C | Missense Mutation (SNP) | VAF 76/552 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM175 | c.113G>T p.S38I | Missense Mutation (SNP) | VAF 36/308 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- TMEM255A | c.347G>T p.R116I | Missense Mutation (SNP) | VAF 85/625 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMOD3 | c.159G>T p.K53N | Missense Mutation (SNP) | VAF 40/274 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TRAJ18 | c.22G>T p.G8W | Missense Mutation (SNP) | VAF 36/456 reads (8%) | PolyPhen probably damaging (0.995); called by muse, mutect2
- TRIM15 | c.180C>A p.C60* | Nonsense Mutation (SNP) | VAF 44/224 reads (20%) | called by muse, mutect2, varscan2
- TRPA1 | c.396G>T p.M132I | Missense Mutation (SNP) | VAF 71/650 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSNARE1 | c.153G>T p.K51N | Missense Mutation (SNP) | VAF 25/261 reads (10%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2
- TTC5 | c.905G>T p.G302V | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- TTC5 | c.904G>C p.G302R | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- UBL4B | c.403C>G p.Q135E | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- UNC80 | c.8289G>T p.M2763I | Missense Mutation (SNP) | VAF 97/600 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, varscan2
- UPF3B | c.660G>T p.R220S | Missense Mutation (SNP) | VAF 62/680 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2
- USF1 | c.395C>T p.T132I | Missense Mutation (SNP) | VAF 35/236 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- USP47 | c.3823G>T p.G1275C (on ENST00000399455 / NM_001372095.1; = p.G1187C on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VWC2 | c.415C>A p.P139T | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2
- VWC2 | c.835T>A p.C279S | Missense Mutation (SNP) | VAF 38/359 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WAPL | c.812G>T p.R271L | Missense Mutation (SNP) | VAF 48/372 reads (13%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR87 | c.4374G>T p.Q1458H | Missense Mutation (SNP) | VAF 43/323 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- WNT9A | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- WTAP | c.1138C>T p.H380Y | Missense Mutation (SNP) | VAF 29/235 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2
- XDH | c.3613G>T p.G1205C | Missense Mutation (SNP) | VAF 55/407 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XIRP2 | c.9335C>A p.T3112N (on ENST00000628543; = p.T3287N on NM_152381.6) | Missense Mutation (SNP) | VAF 74/804 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.168); called by muse, mutect2
- XKR6 | c.1196del p.F399Sfs*24 | Frame Shift Del (DEL) | VAF 45/373 reads (12%) | called by mutect2, pindel, varscan2
- XPO1 | c.655G>C p.A219P | Missense Mutation (SNP) | VAF 39/337 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZAN | c.479T>A p.M160K | Missense Mutation (SNP) | VAF 81/627 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ZBTB7C | c.118G>T p.V40L | Missense Mutation (SNP) | VAF 40/222 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- ZC3H12B | c.84C>A p.S28R | Missense Mutation (SNP) | VAF 60/498 reads (12%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZC3H12B | c.1964C>A p.S655* | Nonsense Mutation (SNP) | VAF 31/221 reads (14%) | called by muse, mutect2, varscan2
- ZDBF2 | c.6181G>A p.V2061I | Missense Mutation (SNP) | VAF 50/481 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZDHHC5 | c.1544A>T p.H515L | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.011); called by muse, mutect2
- ZNF157 | c.642_643insT p.E215* | Frame Shift Ins (INS) | VAF 34/254 reads (13%) | called by mutect2, pindel*, varscan2
- ZNF276 | c.434A>T p.Q145L (on ENST00000443381 / NM_001113525.2; = p.Q70L on NM_152287.4) | Missense Mutation (SNP) | VAF 30/254 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- ZNF280A | c.1322A>T p.H441L | Missense Mutation (SNP) | VAF 56/536 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF408 | c.2013G>T p.R671S | Missense Mutation (SNP) | VAF 48/554 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.01); called by muse, mutect2
- ZNF432 | c.14A>T p.Q5L | Missense Mutation (SNP) | VAF 22/163 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- ZNF469 | c.4166A>T p.Q1389L (on ENST00000437464; = p.Q1417L on NM_001367624.2) | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2
- ZNF536 | c.3478G>T p.D1160Y | Missense Mutation (SNP) | VAF 95/441 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- ZNF676 | c.1258G>C p.A420P (on ENST00000650058; = p.A388P on NM_001001411.3) | Missense Mutation (SNP) | VAF 42/414 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); called by muse, varscan2
- ZNF70 | c.958A>T p.S320C | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- ZNF804A | c.681G>C p.E227D | Missense Mutation (SNP) | VAF 47/453 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- ZNF831 | c.3995G>T p.R1332M | Missense Mutation (SNP) | VAF 55/300 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- ABI2 | c.1128C>T p.S376= (on ENST00000295851 / NM_001375719.1; = p.S309= on NM_005759.7 and 35 other RefSeq transcripts) | Silent (SNP) | VAF 25/258 reads (10%) | catalogued as rs867014560; called by muse, mutect2, varscan2
- ACOT4 | c.351A>T p.G117= | Silent (SNP) | VAF 25/298 reads (8%) | called by muse, mutect2
- ACTRT1 | c.364C>T p.L122= | Silent (SNP) | VAF 67/391 reads (17%) | catalogued as rs1286397455, COSV100947503; called by muse, mutect2, varscan2
- ADAMTSL4 | c.1659C>A p.T553= | Silent (SNP) | VAF 31/244 reads (13%) | catalogued as rs766045112; called by muse, mutect2, varscan2
- ADRB3 | c.402C>T p.D134= | Silent (SNP) | VAF 28/304 reads (9%) | called by muse, mutect2, varscan2
- AGO4 | c.2103G>T p.R701= | Silent (SNP) | VAF 38/510 reads (7%) | catalogued as rs1203031332; called by muse, mutect2
- AMIGO1 | c.489C>G p.L163= | Silent (SNP) | VAF 30/404 reads (7%) | called by muse, mutect2
- ANK2 | c.6027A>G p.G2009= | Silent (SNP) | VAF 86/585 reads (15%) | called by muse, mutect2, varscan2
- ANKRD30A | c.192C>A p.I64= (on ENST00000611781; = p.I8= on NM_052997.2) | Silent (SNP) | VAF 43/462 reads (9%) | catalogued as COSV100654460; called by muse, mutect2
- ARHGAP30 | c.174G>T p.G58= | Silent (SNP) | VAF 13/142 reads (9%) | called by muse, mutect2, varscan2
- ARMC5 | c.12G>A p.A4= | Silent (SNP) | VAF 14/304 reads (5%) | catalogued as rs1339700834, COSV51655424; called by muse, mutect2
- ASAP2 | c.1293G>T p.T431= | Silent (SNP) | VAF 16/139 reads (12%) | called by muse, mutect2, varscan2
- BRAF | c.312G>T p.G104= | Silent (SNP) | VAF 50/327 reads (15%) | called by mutect2, varscan2
- C20orf203 | c.568C>A p.R190= | Silent (SNP) | VAF 26/108 reads (24%) | called by muse, varscan2
- CA13 | c.702G>C p.A234= | Silent (SNP) | VAF 62/477 reads (13%) | called by muse, mutect2, varscan2
- CCDC110 | c.2187T>C p.N729= | Silent (SNP) | VAF 15/161 reads (9%) | called by muse, mutect2, varscan2
- CDAN1 | c.3177G>A p.Q1059= | Silent (SNP) | VAF 63/333 reads (19%) | called by muse, mutect2, varscan2
- CDH2 | c.2244C>A p.R748= | Silent (SNP) | VAF 45/388 reads (12%) | called by muse, mutect2, varscan2
- CDKL5 | c.732C>T p.F244= | Silent (SNP) | VAF 72/589 reads (12%) | called by muse, mutect2, varscan2
- CFAP65 | c.5664C>T p.V1888= | Silent (SNP) | VAF 11/84 reads (13%) | called by muse, mutect2, varscan2
- CHCHD2 | c.171C>A p.A57= | Silent (SNP) | VAF 30/228 reads (13%) | called by muse, mutect2, varscan2
- COL19A1 | c.489C>A p.L163= | Silent (SNP) | VAF 73/618 reads (12%) | catalogued as rs1273708270; called by muse, mutect2, varscan2
- CPN2 | c.366G>T p.S122= | Silent (SNP) | VAF 39/262 reads (15%) | catalogued as rs202201259; called by muse, varscan2
- CTNND2 | c.1401C>A p.V467= | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as COSV58906535; called by muse, mutect2
- CYSLTR2 | c.744C>A p.T248= | Silent (SNP) | VAF 35/662 reads (5%) | called by muse, mutect2
- DDX17 | c.681G>T p.L227= | Silent (SNP) | VAF 40/389 reads (10%) | called by muse, mutect2, varscan2
- DDX53 | c.111C>G p.G37= | Silent (SNP) | VAF 12/77 reads (16%) | called by muse, mutect2, varscan2
- DGKI | c.1381C>T p.L461= | Silent (SNP) | VAF 30/278 reads (11%) | called by muse, mutect2, varscan2
- DLC1 | c.3045T>C p.S1015= (on ENST00000276297 / NM_001348081.2; = p.S578= on NM_006094.5) | Silent (SNP) | VAF 46/447 reads (10%) | called by muse, mutect2, varscan2
- DNAH8 | c.6084G>A p.L2028= | Silent (SNP) | VAF 21/320 reads (7%) | catalogued as COSV59434883, COSV59445087; called by muse, mutect2
- DNM3 | c.183G>T p.S61= | Silent (SNP) | VAF 50/502 reads (10%) | catalogued as COSV62468142; called by muse, mutect2
- DYSF | c.2122C>T p.L708= | Silent (SNP) | VAF 71/477 reads (15%) | called by muse, mutect2, varscan2
- EEF1E1 | c.282G>T p.L94= | Silent (SNP) | VAF 34/267 reads (13%) | catalogued as COSV101121251; called by muse, mutect2, varscan2
- EIF2AK4 | c.3864G>C p.V1288= | Silent (SNP) | VAF 55/421 reads (13%) | called by muse, mutect2, varscan2
- EPS8L2 | c.1155C>T p.V385= | Silent (SNP) | VAF 29/246 reads (12%) | catalogued as rs774030510; called by muse, mutect2, varscan2
- ERFE | c.753G>T p.A251= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as rs1344183240; called by muse, mutect2, varscan2
- F13B | c.1476A>G p.L492= | Silent (SNP) | VAF 42/352 reads (12%) | called by muse, mutect2, varscan2
- FAM47C | c.1041C>G p.P347= | Silent (SNP) | VAF 45/416 reads (11%) | catalogued as rs781838965, COSV63726283; called by muse, mutect2, varscan2
- FAM71B | c.523C>T p.L175= | Silent (SNP) | VAF 38/249 reads (15%) | called by muse, mutect2, varscan2
- FAT1 | c.8292G>A p.K2764= | Silent (SNP) | VAF 30/568 reads (5%) | catalogued as COSV71672216; called by muse, mutect2
- FBLN2 | c.2520G>T p.P840= | Silent (SNP) | VAF 29/237 reads (12%) | catalogued as COSV99851473; called by muse, mutect2, varscan2
- FLNC | c.7824G>C p.T2608= | Silent (SNP) | VAF 85/561 reads (15%) | called by muse, mutect2, varscan2
- FOXL2 | c.546G>T p.G182= | Silent (SNP) | VAF 34/206 reads (17%) | called by muse, mutect2, varscan2
- FRMD1 | c.1263C>T p.V421= | Silent (SNP) | VAF 35/196 reads (18%) | catalogued as rs1298507321; called by muse, mutect2, varscan2
- GABRA4 | c.1566C>A p.A522= | Silent (SNP) | VAF 83/565 reads (15%) | catalogued as COSV51933824; called by muse, mutect2, varscan2
- HAUS7 | c.129G>T p.G43= | Silent (SNP) | VAF 58/469 reads (12%) | called by mutect2, varscan2
- IGHMBP2 | c.207C>G p.P69= | Silent (SNP) | VAF 73/454 reads (16%) | called by muse, mutect2, varscan2
- IGKV1-8 | c.270T>C p.D90= | Silent (SNP) | VAF 106/838 reads (13%) | catalogued as rs372017192; called by muse, mutect2, varscan2
- IGKV2D-30 | c.168C>A p.T56= | Silent (SNP) | VAF 41/198 reads (21%) | called by mutect2, varscan2
- IL12RB1 | c.1080C>A p.A360= | Silent (SNP) | VAF 37/309 reads (12%) | called by muse, mutect2, varscan2
- INPP5B | c.498A>T p.L166= | Silent (SNP) | VAF 13/152 reads (9%) | catalogued as rs764379984, COSV65958691; called by muse, mutect2
- KIAA0586 | c.129G>T p.G43= (on ENST00000619416 / NM_001244190.2; = p.G58= on NM_014749.5) | Silent (SNP) | VAF 30/367 reads (8%) | called by muse, mutect2
- KIF2B | c.96G>T p.V32= | Silent (SNP) | VAF 74/581 reads (13%) | called by muse, mutect2, varscan2
- KRTAP5-7 | c.474C>T p.P158= | Silent (SNP) | VAF 45/310 reads (15%) | catalogued as rs745607540; called by muse, varscan2
- LIPI | c.135C>T p.F45= | Silent (SNP) | VAF 15/173 reads (9%) | catalogued as rs963989390; called by muse, mutect2
- MEGF6 | c.3546G>A p.P1182= | Silent (SNP) | VAF 7/110 reads (6%) | catalogued as rs928241807; called by muse, mutect2
- MKRN3 | c.336G>T p.G112= | Silent (SNP) | VAF 37/224 reads (17%) | called by muse, mutect2, varscan2
- MPPED1 | c.954C>T p.I318= | Silent (SNP) | VAF 30/263 reads (11%) | catalogued as rs763555881, COSV101342217, COSV68839072; called by muse, mutect2, varscan2
- MRPL13 | c.417G>A p.K139= | Silent (SNP) | VAF 23/182 reads (13%) | called by muse, mutect2, varscan2
- MYOM1 | c.4047G>T p.R1349= | Silent (SNP) | VAF 38/367 reads (10%) | called by muse, mutect2, varscan2
- NELL1 | c.1842C>T p.I614= | Silent (SNP) | VAF 58/744 reads (8%) | catalogued as COSV54334453; called by muse, mutect2
- NIPSNAP2 | c.186C>T p.S62= | Silent (SNP) | VAF 50/425 reads (12%) | called by muse, mutect2, varscan2
- NOTCH1 | c.2289C>G p.V763= | Silent (SNP) | VAF 23/515 reads (4%) | called by muse, mutect2
- NRXN1 | c.2448G>T p.R816= | Silent (SNP) | VAF 33/324 reads (10%) | called by muse, mutect2, varscan2
- NXPE2 | c.1398C>A p.A466= | Silent (SNP) | VAF 55/341 reads (16%) | called by muse, mutect2, varscan2
- OCSTAMP | c.372C>A p.S124= | Silent (SNP) | VAF 51/289 reads (18%) | called by muse, mutect2, varscan2
- OR4C6 | c.633C>A p.I211= | Silent (SNP) | VAF 51/749 reads (7%) | catalogued as rs1170715462, COSV100051880, COSV58605245; called by muse, mutect2
- OR5R1 | c.489T>A p.T163= | Silent (SNP) | VAF 75/464 reads (16%) | catalogued as COSV56571442; called by muse, mutect2, varscan2
- OR6Q1 | c.240G>A p.V80= | Silent (SNP) | VAF 53/308 reads (17%) | catalogued as COSV100110373; called by muse, mutect2, varscan2
- PCDH17 | c.1923C>T p.S641= | Silent (SNP) | VAF 43/279 reads (15%) | called by muse, mutect2, varscan2
- PCDHGA4 | c.2430C>A p.L810= | Silent (SNP) | VAF 117/593 reads (20%) | catalogued as COSV53995707; called by muse, mutect2, varscan2
- PIEZO2 | c.3282C>A p.I1094= | Silent (SNP) | VAF 85/701 reads (12%) | catalogued as COSV57425308; called by muse, mutect2, varscan2
- PPP1R2B | c.9C>A p.A3= | Silent (SNP) | VAF 35/238 reads (15%) | catalogued as COSV70372780; called by muse, mutect2, varscan2
- PSMD4 | c.876G>A p.Q292= | Silent (SNP) | VAF 55/405 reads (14%) | called by muse, mutect2, varscan2
- PTCHD1 | c.2016T>A p.S672= | Silent (SNP) | VAF 58/547 reads (11%) | called by muse, mutect2, varscan2
- PTPRS | c.2907G>C p.V969= | Silent (SNP) | VAF 14/69 reads (20%) | called by muse, mutect2, varscan2
- RASIP1 | c.1719C>T p.L573= | Silent (SNP) | VAF 9/50 reads (18%) | catalogued as rs1433975163; called by muse, mutect2, varscan2
- RBM10 | c.1890G>T p.G630= | Silent (SNP) | VAF 74/446 reads (17%) | called by muse, mutect2, varscan2
- RBM14 | c.1896G>T p.S632= | Silent (SNP) | VAF 59/502 reads (12%) | called by muse, mutect2, varscan2
- RTL9 | c.1572C>A p.S524= | Silent (SNP) | VAF 100/850 reads (12%) | called by muse, mutect2, varscan2
- RTN1 | c.420T>A p.P140= | Silent (SNP) | VAF 34/299 reads (11%) | called by muse, mutect2, varscan2
- SALL1 | c.2983C>A p.R995= | Silent (SNP) | VAF 112/1258 reads (9%) | catalogued as rs746135021, COSV51755278; called by muse, mutect2
- SETD1B | c.1695C>T p.S565= | Silent (SNP) | VAF 11/67 reads (16%) | called by muse, mutect2, varscan2
- SHANK2 | c.2088C>A p.V696= | Silent (SNP) | VAF 32/446 reads (7%) | catalogued as COSV53607614; called by muse, mutect2
- SIGLEC8 | c.1125G>T p.L375= | Silent (SNP) | VAF 41/281 reads (15%) | called by muse, mutect2, varscan2
- SLC17A9 | c.351C>T p.H117= | Silent (SNP) | VAF 14/132 reads (11%) | called by muse, mutect2, varscan2
- SLC27A3 | c.21G>A p.P7= | Silent (SNP) | VAF 34/273 reads (12%) | catalogued as rs200081073; called by muse, mutect2, varscan2
- SLC30A10 | c.816G>C p.P272= | Silent (SNP) | VAF 55/438 reads (13%) | catalogued as COSV63073822; called by muse, mutect2, varscan2
- SLC8A1 | c.2109C>T p.R703= | Silent (SNP) | VAF 64/479 reads (13%) | called by muse, mutect2, varscan2
- SLITRK3 | c.1875C>A p.A625= | Silent (SNP) | VAF 54/418 reads (13%) | catalogued as rs1435631723, COSV53846956; called by muse, mutect2, varscan2
- SOHLH2 | c.834A>G p.Q278= | Silent (SNP) | VAF 89/631 reads (14%) | catalogued as rs1434485332; called by muse, mutect2, varscan2
- STOX1 | c.1188C>T p.S396= | Silent (SNP) | VAF 60/493 reads (12%) | catalogued as rs775671067; called by muse, mutect2, varscan2
- STS | c.1326C>T p.N442= | Silent (SNP) | VAF 72/994 reads (7%) | catalogued as rs765525737; called by muse, mutect2
- STXBP5 | c.2691G>T p.R897= (on ENST00000321680 / NM_001127715.2; = p.R861= on NM_139244.4) | Silent (SNP) | VAF 60/472 reads (13%) | called by muse, mutect2, varscan2
- SYNE3 | c.1086G>T p.A362= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as COSV62079315; called by muse, mutect2, varscan2
- TAF1C | c.1755C>T p.L585= | Silent (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- TBRG4 | c.321C>A p.L107= | Silent (SNP) | VAF 21/150 reads (14%) | called by muse, mutect2, varscan2
- TCP10L2 | c.676C>A p.R226= | Silent (SNP) | VAF 16/142 reads (11%) | called by muse, mutect2
- TESPA1 | c.813C>A p.S271= (on ENST00000316577 / NM_001098815.3; = p.S133= on NM_014796.2 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 100/609 reads (16%) | called by muse, mutect2
- TEX14 | c.1731A>G p.L577= (on ENST00000240361 / NM_001201457.2; = p.L571= on NM_031272.5) | Silent (SNP) | VAF 31/233 reads (13%) | called by mutect2, varscan2
- TMPRSS3 | c.6G>T p.G2= | Silent (SNP) | VAF 58/806 reads (7%) | catalogued as COSV99368645; called by muse, mutect2
- TRGV10 | c.84G>A p.T28= | Silent (SNP) | VAF 71/423 reads (17%) | catalogued as rs1348773116; called by muse, mutect2, varscan2
- TSHZ3 | c.2922C>T p.P974= | Silent (SNP) | VAF 50/436 reads (11%) | catalogued as rs755360689, COSV53680146, COSV99552795; called by muse, mutect2, varscan2
- TTBK1 | c.858C>T p.Y286= | Silent (SNP) | VAF 33/181 reads (18%) | called by muse, mutect2, varscan2
- UPF3B | c.1060C>A p.R354= (on ENST00000276201 / NM_080632.3; = p.R341= on NM_023010.3) | Silent (SNP) | VAF 49/434 reads (11%) | catalogued as COSV52232157; called by muse, varscan2
- VAX1 | c.606G>A p.T202= | Silent (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- XAGE3 | c.196C>T p.L66= | Silent (SNP) | VAF 40/380 reads (11%) | called by muse, mutect2, varscan2
- XPNPEP2 | c.1044C>T p.S348= | Silent (SNP) | VAF 44/387 reads (11%) | catalogued as COSV64368641; called by muse, mutect2, varscan2
- YY2 | c.390A>G p.T130= | Silent (SNP) | VAF 29/215 reads (13%) | called by muse, mutect2, varscan2
- ZFR2 | c.1248C>A p.P416= | Silent (SNP) | VAF 20/116 reads (17%) | called by muse, mutect2
- ZMAT4 | c.90G>C p.V30= | Silent (SNP) | VAF 60/499 reads (12%) | called by muse, mutect2, varscan2
- ZNF37A | c.372G>T p.G124= | Silent (SNP) | VAF 31/261 reads (12%) | called by muse, mutect2, varscan2
- ZNF473 | c.399G>C p.L133= | Silent (SNP) | VAF 18/320 reads (6%) | called by muse, mutect2
- ZNF676 | c.120G>C p.L40= (on ENST00000650058; = p.L8= on NM_001001411.3) | Silent (SNP) | VAF 58/583 reads (10%) | called by muse, mutect2, varscan2
- ZNF831 | c.996C>G p.P332= | Silent (SNP) | VAF 14/115 reads (12%) | called by muse, mutect2, varscan2
- ZNFX1 | c.5289C>T p.L1763= | Silent (SNP) | VAF 40/414 reads (10%) | catalogued as rs973135272; called by muse, mutect2, varscan2
- ADSL | c.-29G>T | 5'UTR (SNP) | VAF 20/149 reads (13%) | called by muse, varscan2
- AF196969.1 | c.-9C>A | 5'UTR (SNP) | VAF 70/535 reads (13%) | called by mutect2, varscan2
- AFF3 | c.54-2605C>T | Intron (SNP) | VAF 30/608 reads (5%) | called by muse, mutect2
- AGAP1 | c.1892-3101C>T | Intron (SNP) | VAF 10/160 reads (6%) | called by muse, mutect2
- AIRE | c.880-50G>T | Intron (SNP) | VAF 34/199 reads (17%) | called by muse, mutect2, varscan2
- ANKRD20A8P | n.717T>C | RNA (SNP) | VAF 83/474 reads (18%) | catalogued as rs782787802; called by muse, mutect2, varscan2
- ARR3 | c.1076+34C>G | Intron (SNP) | VAF 38/331 reads (11%) | called by muse, mutect2, varscan2
- C10orf143 | c.69+4459del | Intron (DEL) | VAF 65/591 reads (11%) | called by mutect2, varscan2
- C19orf12 | chr19:29715364 C>T | 5'Flank (SNP) | VAF 19/67 reads (28%) | catalogued as rs996696226; called by muse, mutect2, varscan2
- C2CD5 | c.801-1069C>G | Intron (SNP) | VAF 72/457 reads (16%) | called by muse, mutect2, varscan2
- CAPN8 | chr1:223539463 G>A | 3'Flank (SNP) | VAF 48/413 reads (12%) | catalogued as rs1419147189; called by muse, mutect2, varscan2
- CCSER1 | c.2217+239161T>A | Intron (SNP) | VAF 28/400 reads (7%) | called by muse, mutect2
- CDKL1 | c.171+5344A>G | Intron (SNP) | VAF 56/305 reads (18%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*2167G>T | 3'UTR (SNP) | VAF 21/174 reads (12%) | called by muse, varscan2
- CICP28 | chr7:56812138 C>A | 3'Flank (SNP) | VAF 6/120 reads (5%) | called by muse, mutect2
- CLRN1 | chr3:150972770 G>A | 5'Flank (SNP) | VAF 128/943 reads (14%) | called by muse, mutect2, varscan2
- CYB5A | c.288+150T>C | Intron (SNP) | VAF 47/404 reads (12%) | called by muse, mutect2, varscan2
- DCAF17 | c.-224G>C | 5'UTR (SNP) | VAF 13/291 reads (4%) | called by muse, mutect2
- DPP6 | c.-11C>T | 5'UTR (SNP) | VAF 36/282 reads (13%) | called by muse, varscan2
- EIF3H | c.289+28920G>T | Intron (SNP) | VAF 59/438 reads (13%) | called by muse, mutect2, varscan2
- EIF3IP1 | n.523C>A | RNA (SNP) | VAF 16/216 reads (7%) | called by muse, mutect2
- EPM2A | c.301+36_301+54del | Intron (DEL) | VAF 19/145 reads (13%) | called by mutect2, pindel, varscan2
- FAM205BP | n.1188G>T | RNA (SNP) | VAF 75/1005 reads (7%) | called by muse, mutect2
- FBXW9 | chr19:12689200 A>G | 3'Flank (SNP) | VAF 45/360 reads (13%) | called by muse, mutect2, varscan2
- FGF13 | c.50-127355A>C | Intron (SNP) | VAF 28/302 reads (9%) | called by muse, mutect2
- FHL1 | c.*539G>A | 3'UTR (SNP) | VAF 33/575 reads (6%) | called by muse, mutect2
- GATA5 | c.*8G>T | 3'UTR (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2, varscan2
- IGFN1 | c.1242-2042G>C | Intron (SNP) | VAF 75/493 reads (15%) | called by muse, mutect2, varscan2
- IGKV1D-43 | c.-1C>A | 5'UTR (SNP) | VAF 42/180 reads (23%) | called by muse, mutect2, varscan2
- INTS8 | c.-10G>T | 5'UTR (SNP) | VAF 33/451 reads (7%) | called by muse, mutect2
- IPO8 | c.640-471C>T | Intron (SNP) | VAF 44/367 reads (12%) | catalogued as rs891418670; called by muse, varscan2
- MIR409 | n.47G>T | RNA (SNP) | VAF 37/129 reads (29%) | called by muse, mutect2, varscan2
- MMP26 | c.-145+92833G>T | Intron (SNP) | VAF 38/270 reads (14%) | called by muse, mutect2, varscan2
- MPRIP | c.2163+3373G>T | Intron (SNP) | VAF 25/120 reads (21%) | called by muse, mutect2, varscan2
- MTM1 | c.*9C>A | 3'UTR (SNP) | VAF 61/518 reads (12%) | catalogued as rs200274146; called by muse, mutect2, varscan2
- NCAM1 | c.-171G>T | 5'UTR (SNP) | VAF 59/535 reads (11%) | called by muse, mutect2, varscan2
- OR7A2P | n.1087C>T | RNA (SNP) | VAF 7/56 reads (13%) | catalogued as rs762686860; called by muse, mutect2, varscan2
- PHKB | c.2427+1018G>T | Intron (SNP) | VAF 60/826 reads (7%) | called by muse, mutect2
- PMS2P3 | n.421G>T | RNA (SNP) | VAF 22/161 reads (14%) | called by muse, mutect2, varscan2
- RFTN1 | c.333-6703C>G | Intron (SNP) | VAF 15/296 reads (5%) | called by muse, mutect2
- RNA5-8SP2 | chr16:34159370 C>A | 5'Flank (SNP) | VAF 12/137 reads (9%) | called by muse, mutect2
- SCART1 | c.2660-331T>A | Intron (SNP) | VAF 34/211 reads (16%) | called by muse, mutect2, varscan2
- SDHAF1 | c.*20G>T | 3'UTR (SNP) | VAF 17/182 reads (9%) | called by muse, mutect2, varscan2
- SINHCAF | c.-21+1154G>T | Intron (SNP) | VAF 4/36 reads (11%) | called by mutect2, varscan2
- SINHCAF | c.-21+930C>G | Intron (SNP) | VAF 30/181 reads (17%) | called by muse, mutect2, varscan2
- SND1 | c.2110+428G>T | Intron (SNP) | VAF 24/230 reads (10%) | called by muse, mutect2, varscan2
- SNORD115-33 | n.31G>T | RNA (SNP) | VAF 52/290 reads (18%) | called by muse, mutect2, varscan2
- SNRNP70 | c.-56G>T | 5'UTR (SNP) | VAF 26/303 reads (9%) | called by muse, mutect2
- SRP19 | c.*863T>G | 3'UTR (SNP) | VAF 129/774 reads (17%) | called by muse, mutect2, varscan2
- SSPOP | n.14033C>T | RNA (SNP) | VAF 53/437 reads (12%) | catalogued as rs1391212310, COSV100947056; called by muse, mutect2, varscan2
- STAG1 | c.902+52A>T | Intron (SNP) | VAF 16/147 reads (11%) | called by muse, varscan2
- STAG1 | c.902+51G>T | Intron (SNP) | VAF 15/145 reads (10%) | catalogued as rs747223120; called by muse, varscan2
- STK11IP | c.945+10C>T | Intron (SNP) | VAF 101/703 reads (14%) | catalogued as rs760044394; called by muse, mutect2, varscan2
- STK26 | c.273+647A>T | Intron (SNP) | VAF 41/385 reads (11%) | called by muse, mutect2, varscan2
- TBXAS1 | c.333+1802G>C | Intron (SNP) | VAF 29/294 reads (10%) | called by muse, mutect2
- TGFB1I1 | c.714+12C>A | Intron (SNP) | VAF 13/167 reads (8%) | called by muse, mutect2
- VSTM2A | c.634+3730A>G | Intron (SNP) | VAF 100/648 reads (15%) | called by muse, mutect2, varscan2
- WT1 | chr11:32437953 C>G | 5'Flank (SNP) | VAF 38/293 reads (13%) | called by muse, mutect2, varscan2
- ZNF252P | chr8:145003246 T>C | 5'Flank (SNP) | VAF 51/504 reads (10%) | called by muse, mutect2, varscan2
- ZNF528 | c.272-810G>T | Intron (SNP) | VAF 45/270 reads (17%) | called by muse, mutect2, varscan2
- ZNF575 | chr19:43531852 C>G | 5'Flank (SNP) | VAF 41/242 reads (17%) | called by muse, varscan2
